Somatic mutation profile of tumor specimen 0DRE0X from CCDI case PBCFJL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.1 years (5,864 days).
Specimen 0DRE0X: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4424ef29-3b88-4bbf-8ae9-59cbba7d1b94.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRE0F (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ae7cd301-10d6-42cf-bdf0-0848c3c4e323

The open-access MAF lists 13 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Frame Shift Del 1, Intron 1, 3'Flank 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 75/586 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BRAF | c.1061G>T p.R354L | Missense Mutation (SNP) | VAF 98/878 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.758); catalogued as COSV56135729; called by muse, mutect2, varscan2
- MICALL1 | c.2338C>T p.R780W | Missense Mutation (SNP) | VAF 108/822 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs575389316; called by muse, mutect2, varscan2
- MYO1G | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 74/722 reads (10%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.924); catalogued as rs377581554; called by muse, mutect2
- OR4C15 | c.836G>A p.R279K (on ENST00000314644; = p.R225K on NM_001001920.2) | Missense Mutation (SNP) | VAF 83/857 reads (10%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.044); catalogued as rs763560653, COSV58952052; called by muse, mutect2, varscan2
- MCCC2 | c.553T>G p.F185V | Missense Mutation (SNP) | VAF 54/479 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MCCC2 | c.554T>G p.F185C | Missense Mutation (SNP) | VAF 56/485 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NPVF | c.576G>T p.L192F | Missense Mutation (SNP) | VAF 60/758 reads (8%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.916); called by muse, mutect2
- TMEM65 | c.47_59del p.L16Rfs*47 | Frame Shift Del (DEL) | VAF 24/280 reads (9%) | called by mutect2, pindel
- USP27X | c.793G>A p.D265N | Missense Mutation (SNP) | VAF 101/443 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- OTUD6A | c.204C>T p.D68= | Silent (SNP) | VAF 72/332 reads (22%) | catalogued as COSV57973566; called by muse, mutect2, varscan2
- ANK3 | c.4074+79C>T | Intron (SNP) | VAF 18/112 reads (16%) | catalogued as rs753176062; called by muse, mutect2, varscan2
- OR5R1 | chr11:56412872 C>T | 3'Flank (SNP) | VAF 167/836 reads (20%) | catalogued as rs574149874; called by muse, mutect2, varscan2
